Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040031-09A.1 (aliquot TARGET-15-SJMPAL040031-09A.1-01D) from TARGET case TARGET-15-SJMPAL040031, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,054 days).
Specimen TARGET-15-SJMPAL040031-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b857b87-02b7-4da0-aab4-ab480925f464.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040031-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040031-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc0b7f32-a7ef-4a8c-bdcb-7420ea32a929

The open-access MAF lists 11 somatic variants for this specimen: 3 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 2, Frame Shift Ins 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HEATR5B | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, varscan2
- SRSF2 | c.497_498insGCCC p.R167Pfs*49 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by pindel, varscan2
- BCL11B | c.1395G>T p.S465= (on ENST00000357195 / NM_001282237.2; = p.S394= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV61734577; called by muse, mutect2
- GABRQ | c.946C>A p.R316= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV64780814; called by muse, mutect2
- MICAL1 | c.1134G>T p.V378= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- PPP1R26 | c.2151G>A p.A717= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs527358949; called by muse, varscan2
- SPRR2B | c.189C>T p.C63= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs1035683029, COSV58797405; called by muse, mutect2, varscan2
- TTLL8 | c.1770G>T p.P590= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1037204206, COSV56729349; called by muse, mutect2, varscan2
- DSC3 | c.-33G>T | 5'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- GCGR | c.1176+35C>A | Intron (SNP) | VAF 3/43 reads (7%) | catalogued as rs1010070308; called by muse, mutect2
